Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70R, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70R-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology	Final Results
--------------------	---------------

Surgical Pathology

Final

CASE NUMBER:

7

DIAGNOSIS:

1. Adrenal gland, right, adrenalectomy: Consistent with pheochromocytoma.
2. Gallbladder, cholecystectomy: Gallbladder with cholelithiasis and mild chronic inflammation.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: Pheochromocytoma / Biliary Colic.

Specimen Taken For Protocol: 01 - Yes.

Allocate Order to Protocol:

PROCEDURE: Operative Findings: Right Adrenal Pheo / Gall Bladder w/ mild chronic inflammation.

Post-Operative Diagnosis: Pheochromocytoma / Biliary Colic.

Pre-Operative Diagnosis: Pheochromocytoma / Biliary Colic.

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, RIGHT
2. GALLBLADDER

GROSS DESCRIPTION: Received are 2 freshly submitted specimens, each in containers labeled with the patient's name, medical record number, and further specified as follows:

1. "Right adrenal gland" is an adrenal gland with associated fat, overall 8.4 x 5 x 3.5 cm and 51 grams. The external surface is inked black. The specimen is bisected revealing a variegated pink-red nodule, 8.4 x 4 x 3.5 cm, positioned in the medullary aspect. The nodule is partially covered by cortex up to 0.4 cm in thickness. Gross photographs are taken. Approximately 50% of tissue from the center of the nodule and 0.8 x 0.4 x 0.3 cm of normal-appearing adrenal gland are procured for Approximately 1 x 1 x 0.5 cm of normal-appearing periadrenal fat is procured for The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. The procurement was performed by on Received in Surgical Pathology is a specimen

[page 2 of 2]
Final Results

Surgical Pathology

matching the above description. The specimen is serially sectioned and representative sections are submitted into cassettes labeled . The remaining tissue is returned to formalin.

2. "Gallbladder" is an intact turgid gallbladder, 8.6 x 3.5 x 3.2 cm. The serosa is smooth and glistening. The liver bed is rough and irregular and otherwise unremarkable. The cystic duct is 0.3 cm in diameter, patent, and closed by surgical clips. The lumen is partially filled with innumerable yellow-green multifaceted gallstones ranging from minute to 0.9 cm in greatest dimensions and in the aggregate 6.5 x 2 x 1 cm. The mucosa is tan-green and slightly trabeculated. The wall is up to 0.3 cm in thickness. Received in Surgical Pathology is a specimen matching the above description. The cystic duct margin is removed and entirely submitted in a cassette labeled and representative sections of the mucosa are submitted into a cassette labeled . The remaining tissue is returned to formalin.

Gross Description dictated by
Gross Description dictated by

Additional

Accessioned:
Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID:

Do not file in Medical Record

Requested By:

Source: NCI Genomic Data Commons file d99bac99-42eb-4f09-9762-087db9e345b0 (TCGA-QR-A70R.F1923FE5-5C71-492E-ADAD-7FB276360FE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).